TCGA case TCGA-MQ-A6BR — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Washington University - NYU. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/00397ce0-a931-46dd-9407-c1c6a14c39f1

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 55 years; Vital status: Alive.

Diagnoses (7)
1. Epithelioid mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 55.1 years (20,134 days); Year of diagnosis: 2008; Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T1b; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Days to last follow up: 2,090 days (5.7 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment end: 117 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pemetrexed Disodium; Days to treatment end: 117 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment end: 665 days (1.8 years); Treatment outcome: Complete Response; Treatment anatomic sites: Distant Site.
   Recorded as not given: Pleurodesis, NOS, prior to procurement.
2. Diagnosis record without a diagnosis name: Tissue or organ of origin: Thorax, NOS; Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 56.8 years (20,763 days); Days to diagnosis: 629 days (1.7 years); Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Thorax, NOS. Age at diagnosis: 56.9 years (20,799 days); Days to diagnosis: 665 days (1.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.
4. Diagnosis record without a diagnosis name: Tissue or organ of origin: Thorax, NOS; Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 58.5 years (21,378 days); Days to diagnosis: 1,244 days (3.4 years); Prior treatment: Yes.
5. Progression of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Pleura, NOS. Age at diagnosis: 58.5 years (21,378 days); Days to diagnosis: 1,244 days (3.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,244 days (3.4 years).
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.
6. Diagnosis record without a diagnosis name: Tissue or organ of origin: Thorax, NOS; Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 59.4 years (21,708 days); Days to diagnosis: 1,574 days (4.3 years); Prior treatment: Yes.
7. Progression of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Pleura, NOS. Age at diagnosis: 59.4 years (21,708 days); Days to diagnosis: 1,574 days (4.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,574 days (4.3 years).

Follow-up (9 entries)
- Day 629 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Thorax, NOS.
- Day 665 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Thorax, NOS; Days to progression: 665 days (1.8 years).
- Day 1,244 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Thorax, NOS.
- Day 1,244 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 1,244 days (3.4 years).
- Day 1,574 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 1,574 days (4.3 years).
- Day 1,574 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Thorax, NOS.
- Days to follow up: 1,575 days (4.3 years); Disease response: With Tumor.
- Days to follow up: 1,894 days (5.2 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 2,090.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-MQ-A6BR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 40 mg.
  Slide TCGA-MQ-A6BR-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-MQ-A6BR-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-MQ-A6BR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; History asbestos exposure: No.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment 2: Pharmaceutical therapy drug name: Alimta.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,090 days; disease-specific survival: no event (censored), 2,090 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 665 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-MQ-A6BR-01A-11D-A34B-01): tumor purity 0.62, ploidy 2.1, whole-genome doublings 1.
